Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3966, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3966-01A (Primary Tumor).

This is an unequivocal finding in the sense of an adenocarcinoma of the colon (Block A) of the mucinous adenocarcinoma type (thus G3), with penetration of all parietal layers and vascular infiltration, thus pT3, L1, V1, with free resection margins in the mucosal region with a regular mucosa, submucosa and muscularis, with free resection margins in the ligature region with mature mesenchymal structures, with a chronic recurrent appendicitis with fecal impaction.

Tumor classification:

ICDO-DA-M G 3

pT3, L1, V1, pN0 (0/14)

Source: NCI Genomic Data Commons file 64a437f3-ad54-4197-9c91-5549a61cd479 (TCGA-AA-3966.D2C3087B-9B52-4958-859A-F2EE18FFE6A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).